Somatic mutation profile of tumor specimen MP2PRT-PAUUCT-TMP1-A (aliquot MP2PRT-PAUUCT-TMP1-A-1-0-D-A83P-36) from MP2PRT case MP2PRT-PAUUCT, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.5 years (1,635 days).
Specimen MP2PRT-PAUUCT-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 68b46377-6732-4b44-bffc-33c47c286433.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUUCT-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUUCT-NB1-A-1-0-D-A83P-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/03e605d8-9501-4392-9b55-2327417d6980

The open-access MAF lists 24 somatic variants for this specimen: 16 protein-altering or splice-affecting, 6 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 6, Intron 1, 3'UTR 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CWC25 | c.143G>A p.R48K | Missense Mutation (SNP) | VAF 208/598 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.376); catalogued as rs765371429; called by muse, mutect2
- HEPACAM | c.121C>T p.R41C | Missense Mutation (SNP) | VAF 110/305 reads (36%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.744); catalogued as rs917878985, COSV100005691, COSV53429933; called by muse, mutect2, varscan2
- NEBL | c.584C>T p.A195V | Missense Mutation (SNP) | VAF 77/186 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.019); catalogued as COSV65799738; called by muse, mutect2, varscan2
- PDZRN4 | c.3071C>T p.T1024M (on ENST00000402685 / NM_001164595.2; = p.T766M on NM_013377.4) | Missense Mutation (SNP) | VAF 30/350 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.279); catalogued as rs754588707, COSV54197613; called by muse, mutect2
- PLEKHG4 | c.1889C>T p.A630V | Missense Mutation (SNP) | VAF 28/749 reads (4%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs775644209, COSV58574670; called by muse, mutect2
- WNK4 | c.2017C>T p.R673* | Nonsense Mutation (SNP) | VAF 152/355 reads (43%) | catalogued as rs749704694; called by muse, mutect2, varscan2
- CAPN6 | c.1718C>T p.T573I | Missense Mutation (SNP) | VAF 34/177 reads (19%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.565); called by muse, mutect2, varscan2
- CHD5 | c.4285C>T p.R1429W | Missense Mutation (SNP) | VAF 160/390 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CHST8 | c.467G>A p.R156H | Missense Mutation (SNP) | VAF 279/617 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CHTF18 | c.1194G>A p.M398I | Missense Mutation (SNP) | VAF 120/304 reads (39%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.615); called by muse, mutect2, varscan2
- COL12A1 | c.93G>C p.L31F | Missense Mutation (SNP) | VAF 91/204 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- EMX2 | c.614G>A p.R205Q | Missense Mutation (SNP) | VAF 15/427 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- FOXQ1 | c.661C>G p.P221A | Missense Mutation (SNP) | VAF 96/232 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PABPC1 | c.70G>A p.E24K | Missense Mutation (SNP) | VAF 21/622 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SLC45A4 | c.517G>A p.D173N (on ENST00000517878 / NM_001286646.2; = p.D122N on NM_001080431.2) | Missense Mutation (SNP) | VAF 35/676 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- THUMPD3 | c.506G>A p.R169K | Missense Mutation (SNP) | VAF 10/296 reads (3%) | SIFT tolerated (0.9); PolyPhen benign (0); called by muse, mutect2
- EXT1 | c.1473C>G p.V491= | Silent (SNP) | VAF 164/468 reads (35%) | called by muse, mutect2
- GALNT6 | c.66C>T p.L22= | Silent (SNP) | VAF 201/464 reads (43%) | called by muse, mutect2, varscan2
- IGKV2-30 | c.327G>A p.G109= | Silent (SNP) | VAF 43/150 reads (29%) | catalogued as rs780259352; called by muse, mutect2, varscan2
- MAP2K2 | c.1038C>T p.V346= | Silent (SNP) | VAF 42/512 reads (8%) | called by muse, mutect2
- MCM7 | c.93C>T p.F31= | Silent (SNP) | VAF 87/247 reads (35%) | called by muse, mutect2, varscan2
- MYO18B | c.7665C>T p.D2555= | Silent (SNP) | VAF 116/264 reads (44%) | catalogued as rs374395239; called by muse, mutect2, varscan2
- FBLN2 | c.2155+1985C>T | Intron (SNP) | VAF 138/390 reads (35%) | catalogued as rs1272543945, COSV55486373, COSV99852504; called by muse, mutect2, varscan2
- TVP23A | c.*1924C>T | 3'UTR (SNP) | VAF 46/628 reads (7%) | called by muse, mutect2
